Surgical pathology report (de-identified scan), TCGA case TCGA-B0-5094, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-B0-5094-01A (Primary Tumor).

FINAL DIAGNOSIS

PART 1: KIDNEY, LEFT, LAPAROSCOPIC NEPHRECTOMY:

- A. RENAL CELL CARCINOMA, CONVENTIONAL (CLEAR) CELL TYPE.
- B. FUHRMAN'S NUCLEAR GRADE IS II OF IV.
- C. THE GREATEST DIAMETER OF THE NEOPLASM IS 8.0 CM.
- D. THE NEOPLASM IS CONFINED WITHIN THE CAPSULE.
- E. THE NEOPLASM INVOLVES THE INKED SURGICAL MARGIN OF THE RENAL VEIN.
- F. ALL OTHER SURGICAL MARGINS ARE NEGATIVE.
- G. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- H. THE ADRENAL GLAND IS UNREMARKABLE.
- I. TNM STAGE: PT3b Nx MX.

Source: NCI Genomic Data Commons file fbbdf15d-76f6-46e2-80f2-3a18ec48bd53 (TCGA-B0-5094.8D162190-9A01-4121-91BA-AB334BDEE84F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).